HCMI case HCM-CSHL-0393-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): first patient visit.
https://portal.gdc.cancer.gov/cases/a691cd0c-1878-47a6-8a0f-37e4fe12d20a

Demographics
Sex at birth: male; Days to birth: -27,375 days (74.9 years before the index date); Year of birth: 1943; Vital status: Dead; Days to death: 194 days.

Diagnoses (2)
1. Carcinoma, undifferentiated, NOS (the primary disease): ICD-O-3 morphology code: 8020/3; ICD-10 code: C18.0; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; AJCC staging edition: 7th; Tumor grade: G4; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 49 days; Days to treatment end: 121 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 49 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.
2. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8020/6; ICD-10 code: C77.0; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 137 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 182 cm; BMI: 23.8.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-CSHL-0393-C18-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-CSHL-0393-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
